Somatic mutation profile of tumor specimen TCGA-VQ-A91V-01A (aliquot TCGA-VQ-A91V-01A-11D-A410-08) from TCGA case TCGA-VQ-A91V, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 58.9 years (21,505 days).
Specimen TCGA-VQ-A91V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e12ee44-f6c1-448a-b331-4843e4b16468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91V-10B (Blood Derived Normal), aliquot TCGA-VQ-A91V-10B-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1c36c7-0241-4e26-be20-83409c37efca

The open-access MAF lists 256 somatic variants for this specimen: 196 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 53, Nonsense Mutation 5, RNA 4, Splice Region 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs864622263, CM023346, CM980321, COSV100445285, COSV58693684, COSV58729402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.400T>C p.F134L | Missense Mutation (SNP) | VAF 22/25 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267605077, COSV52660909, COSV52676112, COSV52697695, COSV52923862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACKR1 | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100929622; called by muse, mutect2, varscan2
- ADAMTS8 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV99961332; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3239T>A p.F1080Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.196); catalogued as COSV99720370; called by muse, mutect2, varscan2
- ADGRB3 | c.2308T>G p.L770V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs755820853, COSV65408728; called by muse, mutect2, varscan2
- AGBL1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV101408167; called by muse, mutect2, varscan2
- AL592490.1 | c.2210A>G p.D737G | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101308253; called by muse, mutect2, varscan2
- ALOX5 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1267693488, COSV65551871; called by muse, mutect2, varscan2
- ANO3 | c.2018T>G p.L673R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99884586; called by muse, mutect2, varscan2
- AR | c.2427A>C p.K809N | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101018990; called by muse, mutect2, varscan2
- ASTN1 | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56067149; called by muse, mutect2, varscan2
- ASXL1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167333195, COSV60104105; called by muse, mutect2, varscan2
- ATG4D | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 65/97 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149332891, COSV58762326; called by muse, varscan2
- AVPR2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs368567969, COSV61686273; called by muse, mutect2, varscan2
- BCL11A | c.1160A>G p.K387R (on ENST00000335712 / NM_001365609.1; = p.K421R on NM_018014.4) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1156752105, COSV100186195; called by muse, mutect2, varscan2
- BRINP3 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100819184, COSV66513164; called by muse, mutect2, varscan2
- C8A | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs771230899, COSV100776623; called by muse, mutect2, varscan2
- CCDC148 | c.1260dup p.Y421Ifs*29 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | catalogued as rs761447262; called by mutect2, varscan2
- CCNA1 | c.208A>C p.T70P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV99714761; called by muse, mutect2, varscan2
- CD1A | c.223T>G p.F75V | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56860556, COSV99192377; called by muse, mutect2, varscan2
- CD1E | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100937040; called by muse, mutect2, varscan2
- CD99L2 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100692424; called by muse, mutect2, varscan2
- CDC20 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as rs1467610586, COSV100196577; called by muse, mutect2, varscan2
- CDH2 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52295143; called by muse, mutect2, varscan2
- CDH8 | c.1197A>C p.E399D | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV100183472; called by muse, mutect2, varscan2
- CHD1 | c.2374C>A p.L792I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs758876162, COSV99399713; called by muse, mutect2, varscan2
- CLMP | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV101507433; called by muse, mutect2, varscan2
- CNGA2 | c.414T>G p.D138E | Missense Mutation (SNP) | VAF 100/126 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV100323862; called by muse, mutect2, varscan2
- CNTLN | c.1454A>C p.N485T | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV99265141; called by muse, mutect2, varscan2
- COL24A1 | c.1226A>C p.K409T | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as COSV100993782; called by muse, mutect2, varscan2
- COL8A1 | c.2186G>A p.G729E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1389343893, COSV99658172; called by muse, mutect2, varscan2
- CPXCR1 | c.54T>G p.N18K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52162862; called by muse, mutect2, varscan2
- CSMD1 | c.2446A>G p.R816G (on ENST00000520002; = p.R815G on NM_033225.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100151893; called by muse, mutect2, varscan2
- CSMD3 | c.7057T>G p.F2353V (on ENST00000297405 / NM_001363185.1; = p.F2249V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99842637; called by muse, mutect2, varscan2
- CTNNA3 | c.2354T>G p.V785G | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV101041523; called by muse, mutect2, varscan2
- CTNND1 | c.2091G>A p.T697= (on ENST00000399050 / NM_001085458.2; = p.T691= on NM_001331.3) | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as COSV62385655; called by muse, mutect2, varscan2
- CUX2 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.29); PolyPhen benign (0.219); catalogued as COSV99920347; called by muse, mutect2, varscan2
- DCC | c.2212A>G p.T738A | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100502004; called by muse, mutect2, varscan2
- DCLK1 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55189569, COSV55200088; called by muse, mutect2, varscan2
- DCLK1 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55185720; called by muse, mutect2, varscan2
- DCSTAMP | c.1305A>C p.E435D | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV99886813; called by muse, mutect2, varscan2
- DDX60L | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs748422357, COSV52710829; called by muse, mutect2, varscan2
- DNAAF1 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99550455; called by muse, mutect2, varscan2
- DNAH11 | c.5370A>C p.E1790D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.094); catalogued as COSV100180098; called by muse, mutect2, varscan2
- DNAH8 | c.8429G>A p.R2810Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs771436783, COSV59443639; called by muse, mutect2, varscan2
- DPAGT1 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53827774; called by muse, mutect2, varscan2
- DPP10 | c.1647G>T p.L549F | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100070033; called by muse, mutect2, varscan2
- DRC7 | c.1078-1G>T p.X360_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100395814; called by muse, mutect2, varscan2
- DST | c.12814G>A p.E4272K (on ENST00000361203 / NM_001374722.1; = p.E1860K on NM_015548.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1473867935, COSV99758611; called by muse, mutect2, varscan2
- DYNC2H1 | c.4787T>G p.L1596R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs964733581, COSV100519304, COSV62099675; called by muse, mutect2, varscan2
- EBF1 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV58166123; called by muse, mutect2, varscan2
- EML1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV51743309; called by muse, mutect2, varscan2
- EPB41L3 | c.3213A>C p.K1071N | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2, varscan2
- EPB41L3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100548239, COSV100549886; called by muse, mutect2, varscan2
- ERBB4 | c.3671A>C p.N1224T | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as COSV100726683; called by muse, mutect2, varscan2
- ERICH3 | c.3117A>C p.E1039D | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV100445148; called by muse, mutect2, varscan2
- EYS | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100676928, COSV60977652; called by muse, mutect2, varscan2
- FAT2 | c.8182C>T p.R2728W | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201629483; called by muse, mutect2, varscan2
- FAT3 | c.7216T>G p.L2406V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53101747; called by muse, mutect2, varscan2
- FAT4 | c.10055A>C p.K3352T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs1386048788, COSV58681601, COSV58686093; called by muse, mutect2, varscan2
- FAT4 | c.11826T>G p.N3942K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100629536; called by muse, mutect2, varscan2
- FBXO24 | c.1177G>A p.D393N (on ENST00000241071 / NM_033506.3; = p.D431N on NM_012172.5) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV99575541; called by muse, mutect2, varscan2
- FMN2 | c.4250A>G p.K1417R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs776061186, COSV100146641; called by muse, mutect2, varscan2
- FSD2 | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575241; called by muse, mutect2, varscan2
- FSHR | c.897A>C p.Q299H | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100437660, COSV58623202; called by muse, mutect2, varscan2
- GABRA2 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421381201, COSV62918278, COSV62920665; called by muse, mutect2, varscan2
- GINS1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as rs747353819, COSV99320202; called by muse, mutect2
- GLRB | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100029403, COSV100029938; called by muse, mutect2, varscan2
- GOLIM4 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs368136905; called by muse, mutect2, varscan2
- GPC6 | c.1538T>C p.V513A | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV100989597; called by muse, mutect2, varscan2
- GRM1 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99268090; called by muse, mutect2, varscan2
- GRM3 | c.80A>C p.N27T | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100862482, COSV100862731; called by muse, mutect2, varscan2
- HAUS7 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV57850301; called by muse, mutect2, varscan2
- HFM1 | c.2070C>T p.S690= | Splice Region (SNP) | VAF 23/67 reads (34%) | catalogued as rs1252951333, COSV99646497; called by muse, mutect2, varscan2
- HRNR | c.2111A>C p.K704T | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100913750; called by muse, mutect2, varscan2
- IGSF8 | c.1439G>A p.W480* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as rs973530462, COSV100081776, COSV58758289; called by muse, mutect2
- IL12A | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756430989, COSV59758792; called by muse, mutect2, varscan2
- IRX6 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51859779, COSV99306692; called by muse, mutect2, varscan2
- JARID2 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100522124; called by muse, mutect2, varscan2
- KCNT1 | c.823C>T p.R275W (on ENST00000488444; = p.R294W on NM_020822.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369101729; called by muse, mutect2, varscan2
- KHDRBS2 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs749292989, COSV99836189; called by muse, mutect2, varscan2
- KLHL4 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100910064; called by muse, mutect2, varscan2
- KLHL4 | c.2087A>C p.E696A | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100910065; called by muse, mutect2, varscan2
- KRCC1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs770395461, COSV100712854, COSV100712887; called by muse, mutect2, varscan2
- LMOD1 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66173700; called by mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRRC18 | c.202T>G p.S68A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99630256; called by muse, mutect2, varscan2
- MAGEB1 | c.493T>G p.L165V | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.823); catalogued as COSV100975062; called by muse, mutect2, varscan2
- MAGEB2 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100975725; called by muse, mutect2, varscan2
- MAGEB3 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776429024, COSV100854760, COSV64397059; called by muse, mutect2, varscan2
- MTHFD1 | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99387172; called by muse, mutect2, varscan2
- MTMR4 | c.1873A>G p.T625A | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV100051296; called by muse, mutect2, varscan2
- MUC5B | c.7574T>A p.L2525Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.193); catalogued as COSV101500614; called by muse, mutect2, varscan2
- MYCT1 | c.163A>C p.S55R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.366); catalogued as COSV65890731, COSV65891152; called by muse, mutect2, varscan2
- MYO1G | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs745931480, COSV99348437; called by muse, mutect2, varscan2
- MYO3A | c.3609A>C p.E1203D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.427); catalogued as COSV99780860; called by muse, mutect2
- NDST4 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV99997375; called by muse, mutect2, varscan2
- NF2 | c.1067T>G p.L356W | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100099012; called by muse, mutect2, varscan2
- NLGN4X | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT tolerated (0.52); PolyPhen benign (0.045); catalogued as COSV99323235; called by muse, mutect2, varscan2
- NOD2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs567793250, COSV100318773; called by muse, mutect2, varscan2
- NPAP1 | c.2518T>G p.F840V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100275556, COSV100275819; called by muse, mutect2, varscan2
- NPY1R | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.871); catalogued as COSV56715663, COSV99649064; called by muse, mutect2, varscan2
- NRK | c.3104A>C p.E1035A | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99688713; called by muse, mutect2, varscan2
- NUMB | c.1154C>A p.A385E (on ENST00000355058; = p.A374E on NM_003744.5) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.328); catalogued as COSV100530461; called by muse, mutect2, varscan2
- OGDHL | c.454T>G p.L152V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV65102689; called by muse, mutect2, varscan2
- OPRK1 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99654276; called by muse, mutect2, varscan2
- OR14C36 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100507606, COSV58601992; called by muse, mutect2, varscan2
- OR2L3 | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100742021, COSV63454855; called by muse, mutect2, varscan2
- OR2T4 | c.697T>G p.L233V | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as rs201934329, COSV100822554; called by muse, mutect2, varscan2
- OR3A1 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759931557, COSV100041792; called by muse, mutect2, varscan2
- OR4M1 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 67/348 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100271430; called by muse, mutect2, varscan2
- OR4N2 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60050647; called by muse, mutect2, varscan2
- OR4N2 | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100269851, COSV60049932; called by muse, mutect2, varscan2
- OR4P4 | c.136T>A p.S46T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.611); catalogued as COSV100111803; called by muse, mutect2, varscan2
- OR51A7 | c.812T>G p.V271G | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100834725; called by muse, mutect2, varscan2
- OR51I1 | c.667A>C p.I223L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100971735; called by muse, mutect2
- OR51M1 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100150142, COSV100150337, COSV60785787; called by muse, mutect2, varscan2
- OR51S1 | c.61T>G p.L21V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV100437554; called by muse, mutect2, varscan2
- OR52J3 | c.679T>G p.F227V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100984911; called by muse, mutect2, varscan2
- OR56A3 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV100290332; called by muse, mutect2, varscan2
- OR5D13 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs112091941, COSV62335074; called by muse, mutect2, varscan2
- OR6N2 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210364, COSV59410636; called by muse, mutect2, varscan2
- PDHA2 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54781843, COSV99757152; called by muse, mutect2, varscan2
- PDIA5 | c.722A>C p.Q241P | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100299624; called by muse, mutect2, varscan2
- PDZRN3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765646730, COSV99731192; called by muse, mutect2, varscan2
- PEG3 | c.4194A>C p.E1398D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV99686961, COSV99689984; called by muse, mutect2, varscan2
- PKHD1 | c.11378C>A p.A3793E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100944977; called by muse, mutect2, varscan2
- POSTN | c.1667A>T p.K556I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV101123435; called by muse, mutect2, varscan2
- POSTN | c.1478A>G p.K493R | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV101123436; called by muse, mutect2, varscan2
- PPP1R3A | c.2605T>G p.L869V | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV99493729; called by muse, mutect2, varscan2
- PPP1R3A | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99493245, COSV99493732; called by muse, mutect2, varscan2
- PRAMEF2 | c.1312A>T p.M438L | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs756363119, COSV99535491; called by muse, mutect2, varscan2
- PREX2 | c.3470A>C p.K1157T | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1425336743, COSV99908973; called by muse, mutect2, varscan2
- PREX2 | c.3982T>G p.L1328V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs557338072, COSV99908976; called by muse, mutect2, varscan2
- PRUNE2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs761914077, COSV100944957; called by muse, mutect2
- PTPN13 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100365210; called by muse, mutect2, varscan2
- PTPRK | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | catalogued as rs1404607466, COSV100949669; called by muse, mutect2, varscan2
- PTPRS | c.5500C>T p.R1834W | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269269717, COSV99509624, COSV99511739; called by muse, mutect2, varscan2
- PYHIN1 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997924999, COSV100932387; called by muse, mutect2, varscan2
- QSOX2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV100699836; called by muse, mutect2, varscan2
- RANBP17 | c.1694T>G p.L565R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101206355; called by muse, mutect2, varscan2
- RFPL4B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764420783, COSV101480716; called by muse, mutect2, varscan2
- RGS7 | c.536A>T p.K179M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100469745; called by muse, mutect2, varscan2
- RIMS2 | c.1264A>C p.S422R (on ENST00000666250 / NM_001348490.2; = p.S230R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.889); catalogued as COSV51681237, COSV51715857; called by muse, mutect2, varscan2
- ROR2 | c.1561T>G p.F521V | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100995997; called by muse, mutect2, varscan2
- RUBCNL | c.1958T>G p.L653R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV59786236; called by muse, mutect2, varscan2
- RYR3 | c.12403C>G p.L4135V (on ENST00000389232; = p.L4136V on NM_001036.6) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV101213518; called by muse, mutect2, varscan2
- SACS | c.11906T>G p.L3969R | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756343663, COSV101207571; called by muse, mutect2, varscan2
- SACS | c.8210T>G p.L2737R | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101207572, COSV66543828; called by muse, mutect2, varscan2
- SACS | c.5279T>G p.L1760R | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV101207573; called by muse, mutect2, varscan2
- SBF2 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV99815159; called by muse, mutect2, varscan2
- SEMA3D | c.1817T>G p.F606C | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.537); catalogued as COSV99407144; called by muse, mutect2, varscan2
- SEMA6D | c.2366A>C p.K789T (on ENST00000316364 / NM_153618.2; = p.K727T on NM_020858.2) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60374610, COSV60385107; called by muse, mutect2, varscan2
- SFRP1 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99617648; called by muse, mutect2, varscan2
- SHCBP1 | c.536G>A p.W179* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | catalogued as COSV100317459; called by muse, mutect2, varscan2
- SLC12A1 | c.66A>C p.Q22H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100372462; called by muse, mutect2, varscan2
- SLC44A5 | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100902351; called by muse, mutect2, varscan2
- SLITRK3 | c.377T>G p.I126S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV99579770; called by muse, mutect2, varscan2
- SORCS1 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV53851773; called by muse, mutect2, varscan2
- SOX17 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs1420347279, COSV52025050; called by muse, mutect2, varscan2
- SPOCK1 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970363; called by muse, mutect2, varscan2
- SPRR3 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV99768714; called by muse, varscan2
- SPTA1 | c.482A>C p.Q161P | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.53); catalogued as COSV100935317, COSV63756608; called by muse, mutect2, varscan2
- SRSF6 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1198247165, COSV99719786; called by muse, mutect2, varscan2
- STAG3 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs770078720, COSV57930165; called by muse, mutect2, varscan2
- STRN3 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs768114573, COSV100670853; called by muse, mutect2, varscan2
- TBL2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782398538, COSV99979615; called by muse, mutect2, varscan2
- TENT4B | c.1310A>G p.D437G (on ENST00000561678 / NM_001365323.2; = p.D422G on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100666135; called by muse, mutect2, varscan2
- TG | c.1129T>G p.F377V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99602338; called by muse, mutect2, varscan2
- TGIF2LX | c.169T>A p.L57M | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99383478; called by muse, mutect2, varscan2
- TLL1 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99288452; called by muse, mutect2, varscan2
- TNN | c.104A>C p.N35T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99512603; called by muse, mutect2, varscan2
- TRHDE | c.2786A>C p.N929T | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99671867; called by muse, mutect2, varscan2
- TRIM60 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100593966; called by muse, mutect2, varscan2
- TTN | c.21584A>C p.K7195T (on ENST00000591111; = p.K6268T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | PolyPhen possibly damaging (0.784); catalogued as COSV100623275; called by muse, mutect2, varscan2
- TUBA3C | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67139593; called by muse, mutect2, varscan2
- UTRN | c.2884C>A p.P962T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs750447450, COSV100840183, COSV100840443; called by muse, mutect2, varscan2
- VN1R2 | c.606A>C p.K202N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100448098; called by muse, mutect2, varscan2
- VWA8 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753556286, COSV55692220; called by muse, mutect2, varscan2
- XDH | c.1553A>C p.K518T | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101052408, COSV65151154; called by muse, mutect2, varscan2
- ZBBX | c.1577T>G p.L526R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV100284672; called by muse, mutect2, varscan2
- ZFPM2 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1563573477, COSV65872946; called by muse, mutect2, varscan2
- ZNF280A | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs766944601, COSV100131172; called by muse, mutect2, varscan2
- ZNF471 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV100340759, COSV100340922; called by muse, mutect2, varscan2
- ZNF536 | c.2855T>C p.V952A | Missense Mutation (SNP) | VAF 72/96 reads (75%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV62834750; called by muse, mutect2, varscan2
- ZNF554 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV100421270; called by muse, mutect2, varscan2
- ZNF793 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as rs1393782258, COSV101495687; called by muse, mutect2, varscan2
- ZNF804A | c.1666A>G p.R556G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100169355; called by muse, mutect2, varscan2
- ZNF813 | c.1679T>G p.F560C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1353586942, COSV101124956; called by muse, mutect2, varscan2
- IGKV1D-42 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PRAMEF20 | c.713T>G p.V238G | Missense Mutation (SNP) | VAF 209/373 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRAMEF8 | c.1035A>C p.Q345H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SPATA31A3 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.226); called by mutect2, varscan2
- STRC | c.3558-1G>A p.X1186_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- VCX3A | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, varscan2
- ADAM29 | c.1110T>C p.S370= | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as COSV100821880; called by muse, mutect2, varscan2
- AMPH | c.1227T>G p.T409= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV100343107; called by muse, mutect2, varscan2
- ANKRD30A | c.2061T>G p.T687= (on ENST00000611781; = p.T631= on NM_052997.2) | Silent (SNP) | VAF 55/114 reads (48%) | catalogued as COSV100653821, COSV100654160; called by muse, mutect2, varscan2
- ATP13A5 | c.1653A>G p.K551= | Silent (SNP) | VAF 113/199 reads (57%) | catalogued as COSV100665508; called by muse, mutect2, varscan2
- C16orf71 | c.726C>A p.P242= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100173055; called by muse, mutect2, varscan2
- CDC42BPB | c.4125C>T p.S1375= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs775515879, COSV100775555; called by muse, mutect2, varscan2
- CNR1 | c.153T>G p.T51= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100759287; called by muse, mutect2, varscan2
- CNTLN | c.3759A>G p.Q1253= | Silent (SNP) | VAF 38/47 reads (81%) | catalogued as COSV99265145; called by muse, mutect2, varscan2
- COA7 | c.265C>T p.L89= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs367564757, COSV101034453; called by muse, mutect2, varscan2
- CREBBP | c.675G>A p.P225= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs140708841; ClinVar: likely benign; called by muse, mutect2
- DNAAF1 | c.804C>T p.V268= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57577480; called by muse, mutect2, varscan2
- DNAH10 | c.11155C>T p.L3719= (on ENST00000409039; = p.L3658= on NM_207437.3) | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV101292474; called by muse, mutect2, varscan2
- EBF3 | c.1518G>A p.S506= (on ENST00000355311 / NM_001375392.1; = p.S497= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs372476626; called by muse, mutect2, varscan2
- GTF2H2 | c.627T>C p.T209= | Silent (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- HIVEP1 | c.2148G>A p.T716= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs774974634, COSV101045493; called by muse, mutect2
- ITPRIP | c.1437C>T p.I479= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs377032318; called by muse, mutect2
- KIF2B | c.1236T>G p.T412= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99275003; called by muse, mutect2, varscan2
- LAMA1 | c.1965T>C p.D655= | Silent (SNP) | VAF 49/63 reads (78%) | catalogued as COSV101057216; called by muse, mutect2, varscan2
- LRP1B | c.7432T>C p.L2478= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs1350745783, COSV101259675, COSV67275125; called by muse, mutect2, varscan2
- LRRC4C | c.1830A>T p.T610= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV99539120; called by muse, mutect2, varscan2
- LY9 | c.1710C>T p.G570= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs763678253, COSV54431972; called by muse, mutect2, varscan2
- MACF1 | c.19749A>G p.K6583= (on ENST00000372915; = p.K4628= on NM_012090.5) | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV99245972; called by muse, mutect2, varscan2
- MAP1B | c.6177C>T p.Y2059= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs567310466, COSV57093150; called by muse, mutect2, varscan2
- MINDY2 | c.88C>T p.L30= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100376524; called by muse, mutect2, varscan2
- MUC5B | c.4578C>T p.D1526= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs376958594; called by muse, mutect2, varscan2
- NCK1 | c.42G>T p.V14= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV99999772; called by muse, mutect2, varscan2
- NID2 | c.2064T>A p.T688= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99357014; called by muse, mutect2, varscan2
- NXPE1 | c.960T>G p.T320= (on ENST00000424269; = p.T178= on NM_152315.5) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99320790; called by muse, mutect2, varscan2
- OR10J3 | c.168T>G p.L56= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as COSV100171837; called by muse, mutect2, varscan2
- OR2T10 | c.564T>C p.S188= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100393773; called by muse, mutect2, varscan2
- OR4K2 | c.576T>C p.T192= | Silent (SNP) | VAF 89/471 reads (19%) | catalogued as COSV100064654, COSV53848339; called by muse, mutect2, varscan2
- OR5T1 | c.837T>G p.T279= | Silent (SNP) | VAF 86/153 reads (56%) | catalogued as rs1202560100, COSV57302542, COSV57304590; called by muse, mutect2, varscan2
- PARD3B | c.2502C>G p.V834= (on ENST00000406610 / NM_001302769.2; = p.V765= on NM_057177.7) | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV100592202; called by muse, mutect2, varscan2
- PCDHB7 | c.846T>C p.S282= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99177212; called by muse, mutect2, varscan2
- PDZRN3 | c.1312C>A p.R438= | Silent (SNP) | VAF 82/110 reads (75%) | catalogued as rs1259011918, COSV55203702, COSV99731195; called by muse, mutect2, varscan2
- PGBD2 | c.957G>A p.K319= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs150759335; called by muse, mutect2, varscan2
- PHF2 | c.444C>T p.D148= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs769570807, COSV63681043; called by muse, mutect2, varscan2
- PRAMEF4 | c.960G>A p.P320= | Silent (SNP) | VAF 116/367 reads (32%) | catalogued as rs750452941, COSV99340015; called by muse, varscan2
- PTGER3 | c.1245A>G p.V415= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV100657247; called by muse, mutect2, varscan2
- SEMA5A | c.2973T>G p.T991= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV101228601; called by muse, mutect2, varscan2
- SLCO1B1 | c.615T>G p.S205= | Silent (SNP) | VAF 188/200 reads (94%) | catalogued as COSV57014377; called by muse, mutect2, varscan2
- STK40 | c.276C>T p.T92= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs779650610, COSV63735511; called by muse, mutect2, varscan2
- STXBP5 | c.1218G>A p.A406= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV51656455; called by muse, mutect2, varscan2
- TAL1 | c.891G>A p.G297= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs759522462, COSV99596276; called by muse, mutect2, varscan2
- TNS1 | c.2562T>G p.T854= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV50729651; called by muse, mutect2, varscan2
- TTN | c.12307A>C p.R4103= (on ENST00000591111; = p.R4057= on NM_003319.4) | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100623277, COSV60374857; called by muse, mutect2, varscan2
- UTRN | c.1104C>T p.S368= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1182924759, COSV100840182; called by muse, mutect2, varscan2
- VWC2 | c.909T>G p.T303= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100514573, COSV61482378; called by muse, mutect2, varscan2
- XPO6 | c.990G>A p.E330= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs1270950817, COSV100485243; called by muse, mutect2, varscan2
- ZNF154 | c.879A>G p.K293= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV101377534; called by muse, mutect2, varscan2
- ZNF311 | c.1219A>C p.R407= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV65853082; called by muse, mutect2, varscan2
- ZNF347 | c.2490C>T p.F830= | Silent (SNP) | VAF 63/176 reads (36%) | catalogued as rs375437187, COSV100498374; called by muse, mutect2, varscan2
- ZSCAN1 | c.1080C>T p.S360= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs144381428; called by muse, mutect2
- DCHS2 | n.5289A>C | RNA (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100602290; called by muse, mutect2, varscan2
- DCHS2 | n.1839C>T | RNA (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100252671; called by muse, mutect2, varscan2
- DCHS2 | n.1247T>C | RNA (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100252672; called by muse, mutect2, varscan2
- LEKR1 | c.*1494T>G | 3'UTR (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100739231; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>G | Intron (SNP) | VAF 22/60 reads (37%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2, varscan2
- OR2T11 | c.-2C>T | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100424907; called by mutect2, varscan2
- RNF217-AS1 | n.2677A>C | RNA (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2
